Gene-level copy-number profile of tumor specimen TCGA-BT-A20P-01A from TCGA case TCGA-BT-A20P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 81.1 years (29,634 days).
Specimen TCGA-BT-A20P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.943b5e2d-dcdd-4b83-a3ed-f6a746a70dd6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A20P-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d15520e-f46b-404f-a8c7-5967ebcb208d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 4,421; copy number 2: 46,967; copy number 3: 8,354; copy number 13: 11; copy number 15: 18; copy number 31: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A20P-01A-11D-A14V-01): tumor purity 0.93, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:163,039,291–163,039,599, 1 gene: MRPL57P6.
- chr9:19,895,800–19,967,994, 4 genes: AL158077.1, AL591222.1, AL591222.2, AL591222.3.
- chr9:20,999,509–21,077,942, 3 genes: HACD4, IFNNP1, IFNB1.
- chr9:21,453,802–22,214,672, 23 genes: MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 39 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,617,915–2,625,320, 29 genes, copy number 13–15 (within-gene range 2–15): FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1, CFAP99, RNF4, AL645924.1, AL645924.2.
- chr9:20,331,446–20,995,955, 10 genes, copy number 31 (within-gene range 0–31): AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B.

Autosomal genes at a single copy (total copy number 1): 3,783. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
